Somatic mutation profile of tumor specimen MMRF_1593_1_BM_CD138pos (aliquot MMRF_1593_1_BM_CD138pos_T1_KBS5U_L04123) from MMRF case MMRF_1593, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.2 years (24,923 days).
Specimen MMRF_1593_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83ecc16-efc4-4a2e-abf1-42ff28e1c967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1593_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1593_1_PB_Whole_C2_KBS5U_L04129; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e91065d2-897e-423e-9d85-6e6bc3eb0e83

The open-access MAF lists 89 somatic variants for this specimen: 17 protein-altering or splice-affecting, 20 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 33, Silent 20, Missense Mutation 16, Intron 8, 5'UTR 4, 5'Flank 3, 3'Flank 3, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 16/273 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- MUC16 | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs1016499955; called by muse, mutect2
- PM20D1 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 87/134 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV65649111; called by muse, mutect2, varscan2
- SDK1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs148919634; called by muse, mutect2, varscan2
- TPSG1 | c.76T>C p.C26R | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057240755; called by muse, mutect2, varscan2
- TSHZ3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs748489070; called by muse, mutect2, varscan2
- ZNF410 | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100206581; called by muse, mutect2, varscan2
- ZNF48 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.024); catalogued as rs914704254; called by muse, mutect2, varscan2
- AKAP6 | c.6910G>A p.E2304K | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ARHGAP32 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BROX | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CXCL3 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT6A | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MMEL1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MTA3 | c.956_957del p.Y319Cfs*12 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by pindel, varscan2
- PTPRK | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIMC1 | c.989T>C p.M330T (on ENST00000443967 / NM_001308196.1; = p.M349T on NM_001308195.2) | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, varscan2
- ALKBH5 | c.606G>A p.V202= | Silent (SNP) | VAF 96/329 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.183C>T p.S61= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- ARHGAP35 | c.2667T>C p.T889= | Silent (SNP) | VAF 108/224 reads (48%) | called by muse, mutect2, varscan2
- BCAM | c.1539C>T p.S513= | Silent (SNP) | VAF 158/350 reads (45%) | catalogued as rs202118823; called by muse, mutect2, varscan2
- CTNND2 | c.1930T>C p.L644= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV58936872; called by muse, mutect2
- FAM222A | c.915G>A p.G305= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- NELFA | c.552G>A p.T184= (on ENST00000542778; = p.T173= on NM_005663.5) | Silent (SNP) | VAF 9/144 reads (6%) | catalogued as rs1325336074, COSV100424610; called by muse, mutect2
- NOX4 | c.229C>A p.R77= | Silent (SNP) | VAF 102/235 reads (43%) | called by muse, mutect2, varscan2
- OR52B4 | c.843C>A p.V281= | Silent (SNP) | VAF 99/236 reads (42%) | catalogued as COSV68769433; called by muse, mutect2, varscan2
- ORC5 | c.783G>A p.L261= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.1344T>C p.S448= | Silent (SNP) | VAF 404/653 reads (62%) | called by muse, mutect2, varscan2
- RANBP17 | c.600T>C p.F200= | Silent (SNP) | VAF 11/18 reads (61%) | called by muse, varscan2
- RHO | c.1029C>T p.S343= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV56214206; called by muse, mutect2
- SETD1B | c.252G>A p.E84= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs1253178850; called by muse, mutect2, varscan2
- SLC27A5 | c.1737G>A p.Q579= | Silent (SNP) | VAF 257/615 reads (42%) | called by muse, mutect2, varscan2
- SLC28A2 | c.1395C>G p.P465= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV100754693; called by muse, mutect2
- SLC52A2 | c.1134G>A p.S378= | Silent (SNP) | VAF 73/154 reads (47%) | catalogued as rs782524983, COSV100095743; called by muse, mutect2, varscan2
- TNXB | c.1605C>T p.H535= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as rs772236159; called by muse, mutect2, varscan2
- TPCN1 | c.1005A>G p.L335= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- UBXN6 | c.153G>A p.E51= | Silent (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- AC005220.1 | chr20:53937102 G>A | 5'Flank (SNP) | VAF 28/111 reads (25%) | catalogued as rs572912229; called by muse, mutect2, varscan2
- AC005324.2 | c.*54C>T | 3'UTR (SNP) | VAF 31/167 reads (19%) | catalogued as rs879089963; called by muse, mutect2, varscan2
- ACYP2 | c.185+3756C>T | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- ADSS2 | c.*883C>T | 3'UTR (SNP) | VAF 136/207 reads (66%) | called by muse, mutect2, varscan2
- AL591135.1 | n.4911G>A | RNA (SNP) | VAF 134/210 reads (64%) | catalogued as rs553320767; called by muse, mutect2, varscan2
- BMF | c.*933G>A | 3'UTR (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- BSDC1 | c.72+82C>G | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- CACNA1H | c.*22C>T | 3'UTR (SNP) | VAF 18/31 reads (58%) | catalogued as rs551855741; called by muse, mutect2, varscan2
- CASK | chrX:41516807 G>T | 3'Flank (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- CCDC70 | c.*125_*133del | 3'UTR (DEL) | VAF 22/40 reads (55%) | called by mutect2, pindel, varscan2
- CPB2 | c.*164A>C | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- CYP26B1 | c.*1072A>G | 3'UTR (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.*1306T>C | 3'UTR (SNP) | VAF 71/151 reads (47%) | called by muse, mutect2, varscan2
- EYS | c.8072-2598_8072-2597insG | Intron (INS) | VAF 4/24 reads (17%) | catalogued as rs202124144; called by pindel, varscan2
- FAM107A | c.-142T>C | 5'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- FSTL5 | c.*1128T>G | 3'UTR (SNP) | VAF 62/149 reads (42%) | called by muse, mutect2, varscan2
- GCNT2 | c.-461T>A | 5'UTR (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- GLT1D1 | c.*257G>T | 3'UTR (SNP) | VAF 41/113 reads (36%) | called by muse, mutect2, varscan2
- HIPK1 | c.*819T>G | 3'UTR (SNP) | VAF 28/124 reads (23%) | catalogued as COSV100478827; called by muse, mutect2, varscan2
- HOXC10 | c.*229C>T | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.-71C>T | 5'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- LATS1 | chr6:149658255 A>G | 3'Flank (SNP) | VAF 7/135 reads (5%) | catalogued as rs1227794699; called by muse, mutect2
- MACC1 | chr7:20136958 T>C | 3'Flank (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- MAEL | chr1:166989275 C>A | 5'Flank (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- MAPK3 | c.170+210T>G | Intron (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- MIS12 | c.*454A>G | 3'UTR (SNP) | VAF 11/21 reads (52%) | catalogued as rs962701373; called by muse, mutect2, varscan2
- MLXIP | c.*1658C>T | 3'UTR (SNP) | VAF 71/147 reads (48%) | catalogued as rs777420043; called by muse, mutect2, varscan2
- MTMR9 | c.1486+837G>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs1334054015; called by muse, mutect2, varscan2
- NSMAF | c.149+3004del | Intron (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- NUP85 | c.*3A>G | 3'UTR (SNP) | VAF 63/178 reads (35%) | called by muse, mutect2, varscan2
- PAPPA | c.*4152T>G | 3'UTR (SNP) | VAF 93/224 reads (42%) | called by muse, mutect2, varscan2
- PAQR5 | c.*2765G>A | 3'UTR (SNP) | VAF 127/278 reads (46%) | called by muse, mutect2, varscan2
- PHLDA3 | c.*206G>T | 3'UTR (SNP) | VAF 78/111 reads (70%) | called by muse, mutect2, varscan2
- PLAA | c.*1202A>C | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- POLR3GL | c.*179G>A | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- PPM1A | c.*1909C>A | 3'UTR (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- PTK2 | c.*1019G>A | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- PTK2 | c.*362A>G | 3'UTR (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- PTPRT | c.2176+12055G>T | Intron (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- RASSF5 | c.*1565C>T | 3'UTR (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- RBM20 | c.*170T>G | 3'UTR (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- RPS3 | c.350+499C>G | Intron (SNP) | VAF 81/164 reads (49%) | called by muse, mutect2, varscan2
- SMAD3 | c.*195G>A | 3'UTR (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- SOGA1 | c.*4830C>T | 3'UTR (SNP) | VAF 4/27 reads (15%) | catalogued as rs1232440580; called by mutect2, varscan2
- SPACA9 | chr9:132878730 C>T | 5'Flank (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- TBRG1 | c.-70C>T | 5'UTR (SNP) | VAF 14/182 reads (8%) | catalogued as rs768093996; called by muse, mutect2
- TG | c.*31C>T | 3'UTR (SNP) | VAF 89/225 reads (40%) | catalogued as rs372394787, COSV99603039; called by muse, mutect2, varscan2
- TMEM184B | c.*1474del | 3'UTR (DEL) | VAF 33/102 reads (32%) | catalogued as rs1264053794; called by mutect2, pindel, varscan2
- ZDHHC4 | c.*298T>G | 3'UTR (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- ZNF141 | c.*656T>G | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- ZNF587 | c.*286G>C | 3'UTR (SNP) | VAF 30/46 reads (65%) | called by muse, varscan2
- ZNF829 | c.*1652A>C | 3'UTR (SNP) | VAF 148/307 reads (48%) | called by muse, mutect2, varscan2
